Somatic mutation profile of tumor specimen TCGA-FI-A2D4-01A (aliquot TCGA-FI-A2D4-01A-12D-A17D-09) from TCGA case TCGA-FI-A2D4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 44.3 years (16,163 days).
Specimen TCGA-FI-A2D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b807f0a-dec5-4014-bccc-52a9f65e7d14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2D4-10A (Blood Derived Normal), aliquot TCGA-FI-A2D4-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17325304-3bd8-4168-b41b-dbbffd645fd1

The open-access MAF lists 401 somatic variants for this specimen: 301 protein-altering or splice-affecting, 91 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 91, Frame Shift Del 83, Nonsense Mutation 14, 3'UTR 5, Frame Shift Ins 4, Splice Region 4, In Frame Del 3, Intron 3, Splice Site 3, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | hotspot (GDC flag); catalogued as COSV61371666; called by muse, mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GALT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs111033795, CM012764, CM950557, COSV100535461; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 38/61 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 98/103 reads (95%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA13 | c.12911A>T p.N4304I | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101291446; called by muse, mutect2, varscan2
- ABHD16B | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs1260956640, COSV99410895; called by muse, mutect2, varscan2
- ACAN | c.6797C>T p.P2266L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs771258166, COSV100719344; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTSL3 | c.3707C>T p.P1236L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as COSV99721317; called by muse, mutect2
- ADARB2 | c.1908del p.F637Sfs*3 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | catalogued as COSV101184579; called by mutect2, pindel, varscan2
- ADRB1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100992320; called by muse, mutect2, varscan2
- AGT | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs146773738; called by muse, mutect2, varscan2
- AL592490.1 | c.1028A>G p.Q343R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101308292; called by muse, mutect2, varscan2
- ALDH16A1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs768111253, COSV99513241; called by muse, mutect2, varscan2
- ANKRD11 | c.4600T>C p.F1534L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99970675; called by muse, mutect2, varscan2
- ANXA7 | c.814-2A>G p.X272_splice (on ENST00000372919 / NM_001320880.2; = p.X250_splice on NM_001156.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/16 reads (63%) | catalogued as COSV100873516; called by muse, mutect2, varscan2
- AP4M1 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.603); catalogued as COSV100385186; called by muse, mutect2, varscan2
- APLP2 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs773428429, COSV99600087; called by muse, mutect2
- APOB | c.3496G>A p.A1166T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV99268237; called by muse, mutect2, varscan2
- AQR | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99334756; called by muse, mutect2, varscan2
- ARFIP2 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99601691; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV57429840; called by mutect2, pindel, varscan2
- ARHGEF10L | c.3541G>A p.A1181T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as rs371858468; called by muse, mutect2, varscan2
- ARID1B | c.5974del p.V1992Wfs*16 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | catalogued as rs749055122; called by mutect2, pindel, varscan2
- ARID5A | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs780034963, COSV100673651; called by muse, mutect2, varscan2
- ARIH2 | c.557A>G p.Q186R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100711415; called by muse, mutect2
- ARL5A | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1351336055, COSV99706820; called by muse, mutect2, varscan2
- ARMC6 | c.536A>G p.Q179R (on ENST00000392336; = p.Q154R on NM_033415.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99523184; called by muse, mutect2, varscan2
- ARMCX2 | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV100168042, COSV100168314, COSV57529376; called by muse, mutect2, varscan2
- ARPP21 | c.1207G>T p.G403W | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51793062, COSV99492221; called by muse, mutect2, varscan2
- ARRB2 | c.475A>C p.S159R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV52618646, COSV99347294; called by muse, mutect2, varscan2
- ARSG | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs150072981, COSV71593277; called by muse, mutect2, varscan2
- ARSI | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100156118; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs746676748; called by mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATF7IP2 | c.1312del p.I438Lfs*21 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs763946306; called by mutect2, pindel, varscan2
- ATOH1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100024584; called by muse, mutect2, varscan2
- BMPR2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as CM1513949, COSV101001676; called by muse, mutect2, varscan2
- C12orf45 | c.551del p.K184Rfs*13 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs777032057; called by mutect2, varscan2
- C20orf194 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99331563; called by muse, mutect2, varscan2
- C6orf136 | c.673T>C p.W225R (on ENST00000376473 / NM_001109938.3; = p.W91R on NM_145029.4) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.852); catalogued as COSV99528207; called by muse, mutect2, varscan2
- CA10 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV53375643, COSV99565267; called by muse, mutect2, varscan2
- CC2D2A | c.188C>A p.P63H (on ENST00000424120 / NM_001378615.1; = p.A98= on NM_020785.2) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.548); catalogued as COSV101052948; called by muse, mutect2, varscan2
- CCDC106 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.3); catalogued as rs1197243058, COSV100454471; called by muse, mutect2, varscan2
- CCDC144A | c.3830A>G p.K1277R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs762166124, COSV100138716; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 35/84 reads (42%) | catalogued as rs535192849; called by mutect2, varscan2
- CDC23 | c.1749del p.T584Hfs*116 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as COSV101203127; called by mutect2, pindel, varscan2
- CHAD | c.423del p.L142Cfs*42 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV51971952; called by mutect2, pindel, varscan2
- CHRNA6 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.703); catalogued as COSV99373432; called by muse, mutect2, varscan2
- CIITA | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs369787912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CKAP5 | c.2530G>T p.G844W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100371481; called by muse, mutect2, varscan2
- CNGB3 | c.2313_2315del p.R772del | In Frame Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs758914061; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- CNTN6 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611889; called by muse, mutect2, varscan2
- COG7 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100207834; called by muse, mutect2, varscan2
- COPZ2 | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1306599573, COSV99133895; called by muse, mutect2, varscan2
- CPPED1 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753327791, CM1514092, COSV99903666; called by muse, mutect2
- CUBN | c.6311C>T p.T2104M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.404); catalogued as rs372611470; called by muse, mutect2, varscan2
- CYSTM1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as rs200380290, COSV55834079; called by muse, mutect2, varscan2
- DAPK1 | c.3991G>A p.A1331T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100802775; called by muse, mutect2
- DCAF12L2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs751386010, COSV63582105; called by muse, mutect2, varscan2
- DDX18 | c.954T>A p.N318K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99604830; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs553532837; called by mutect2, varscan2
- DLL4 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs766050586, COSV99990004; called by muse, mutect2, varscan2
- DNAH11 | c.3235C>G p.L1079V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100181001; called by muse, mutect2, varscan2
- DOCK5 | c.2511C>T p.S837= | Splice Region (SNP) | VAF 4/27 reads (15%) | catalogued as rs1187621630, COSV99377990; called by muse, mutect2
- DPEP3 | c.733A>G p.S245G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99262908; called by muse, mutect2, varscan2
- DPH2 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.112); catalogued as COSV99356659; called by muse, mutect2, varscan2
- DPY19L2 | c.451-2dup p.X151_splice | Splice Site (INS) | VAF 12/26 reads (46%) | catalogued as rs202064990; called by mutect2, varscan2
- DPYS | c.970G>C p.G324R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100680162, COSV60909739; called by muse, mutect2, varscan2
- DRP2 | c.1555G>A p.V519M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100872072; called by muse, mutect2, varscan2
- EIF2AK1 | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1225257469, COSV99552364; called by muse, mutect2, varscan2
- EIF4E1B | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100024910; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs770453803; called by mutect2, varscan2
- ENG | c.1316del p.K439Rfs*52 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as COSV61228377; called by mutect2, pindel, varscan2
- EPB41L3 | c.3023C>T p.T1008M | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300561636, COSV59459558; called by muse, varscan2
- EPHX3 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99691630; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 18/30 reads (60%) | catalogued as rs768793415; called by mutect2, varscan2
- ETF1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100860288; called by muse, mutect2, varscan2
- EXOC7 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs576699784, COSV58745894; called by muse, mutect2, varscan2
- FAM124A | c.1598C>T p.S533L (on ENST00000322475 / NM_001242312.2; = p.S569L on NM_145019.4) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs780052468, COSV54474642; called by muse, mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAT1 | c.11856del p.F3952Lfs*31 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs1166479124; called by mutect2, pindel, varscan2
- FAT4 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101272867; called by muse, mutect2, varscan2
- FBXO33 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99981054; called by muse, mutect2, varscan2
- FCGBP | c.11444G>A p.R3815Q | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs921989912; called by muse, mutect2, varscan2
- FOSB | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100798823; called by muse, mutect2, varscan2
- FOXR1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs782479317, COSV100393000; called by muse, mutect2, varscan2
- FRMD4A | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs745902269, COSV100662545; called by muse, mutect2, varscan2
- FRY | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV66565815; called by muse, mutect2, varscan2
- GABRG3 | c.1244A>T p.Q415L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100410035; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs548474277; called by mutect2, varscan2
- GHRL | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.448); catalogued as rs761310643, COSV99814047; called by muse, mutect2, varscan2
- GJD2 | c.362del p.P121Lfs*4 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs748483263, COSV51749500; called by mutect2, pindel, varscan2
- GLI3 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101230070; called by muse, mutect2, varscan2
- GRAMD4 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV100730671; called by muse, mutect2, varscan2
- GTF2E2 | c.308T>C p.L103S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100577175; called by muse, mutect2, varscan2
- GTF3C4 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs375701353; called by muse, mutect2, varscan2
- GTPBP4 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV62551431; called by muse, mutect2, varscan2
- GUF1 | c.683T>A p.L228H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as COSV99877486; called by muse, mutect2, varscan2
- HELZ | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62378281; called by muse, mutect2, varscan2
- HK1 | c.2215C>T p.Q739* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100068030; called by muse, mutect2, varscan2
- HK2 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769519345, COSV51876176, COSV51880154; called by muse, mutect2, varscan2
- HOXB13 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV51705561, COSV99285373; called by muse, mutect2, varscan2
- IAH1 | c.689G>T p.W230L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100176572; called by muse, mutect2, varscan2
- IFI44L | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV100655129; called by muse, mutect2, varscan2
- IGSF3 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100604825; called by muse, mutect2, varscan2
- IGSF9 | c.154dup p.L52Pfs*27 | Frame Shift Ins (INS) | VAF 20/46 reads (43%) | catalogued as rs753928344; called by mutect2, varscan2
- IL1RL2 | c.1417T>C p.Y473H | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99961131; called by muse, mutect2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- IMMT | c.1628A>G p.Y543C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs771628141, COSV99606668; called by muse, mutect2, varscan2
- ING1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV100312371; called by muse, mutect2, varscan2
- INKA2 | c.559del p.A187Hfs*20 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs751997684, COSV61878369; called by mutect2, pindel, varscan2
- JAG2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs775767402, COSV59306892; called by muse, mutect2, varscan2
- JARID2 | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100522484; called by muse, mutect2, varscan2
- KCNA3 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV63902368; called by muse, mutect2, varscan2
- KCNMA1 | c.268T>A p.F90I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99699816; called by muse, mutect2, varscan2
- KIF11 | c.2933T>A p.V978E | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99586177; called by muse, mutect2, varscan2
- KLHDC7B | c.1687G>A p.A563T (on ENST00000395676; = p.A1204T on NM_138433.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV101192991; called by muse, mutect2, varscan2
- LAMA3 | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs372960002; called by muse, mutect2, varscan2
- LAMB3 | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100620540; called by muse, mutect2, varscan2
- LCK | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288193; called by muse, mutect2, varscan2
- LCT | c.4126C>T p.R1376W | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs1239488063, COSV99930518; called by muse, mutect2, varscan2
- LDLRAD1 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100997635; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LHX9 | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100436094; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 26/46 reads (57%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRP1B | c.6893T>C p.V2298A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV101261428; called by muse, mutect2, varscan2
- LRP6 | c.3493C>T p.Q1165* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV99744561; called by muse, mutect2, varscan2
- LRP8 | c.1202G>A p.C401Y | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036942; called by muse, mutect2, varscan2
- LRRC36 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99339160; called by muse, mutect2, varscan2
- LZTS2 | c.303del p.S102Afs*41 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs1460451498; called by mutect2, pindel, varscan2
- MAD1L1 | c.1642A>G p.N548D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99767632; called by muse, mutect2, varscan2
- MAN2A1 | c.1405G>C p.D469H | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV99811956; called by muse, mutect2, varscan2
- MAP1A | c.3621G>T p.E1207D | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100289273, COSV55805892, COSV55808673; called by muse, mutect2, varscan2
- MAP2K1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV61073567; called by muse, mutect2, varscan2
- MAP3K3 | c.994del p.R332Vfs*75 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs869233786; called by mutect2, pindel, varscan2
- MAP4K3 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99811159; called by muse, mutect2, varscan2
- MC3R | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.028); catalogued as rs760081883, COSV99710876; called by muse, mutect2, varscan2
- MCM2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs35343063; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs750092100; called by mutect2, varscan2
- MED22 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100034861; called by muse, mutect2, varscan2
- MEGF11 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs373679622; called by muse, mutect2
- MGAT3 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs950769862, COSV100361996, COSV100362078; called by muse, mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | catalogued as rs866533107; called by mutect2, pindel, varscan2
- MLXIP | c.2345G>T p.R782L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100039169, COSV59834782; called by muse, mutect2, varscan2
- MMP15 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778686391, COSV99539753; called by muse, mutect2, varscan2
- MYBPC3 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs730880540, COSV99920994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH10 | c.4412G>A p.R1471Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755969165, COSV99346419; called by muse, mutect2, varscan2
- NARF | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs202157877, COSV100559740; called by muse, mutect2, varscan2
- NID1 | c.1844T>C p.F615S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99938378; called by muse, mutect2, varscan2
- NLRC5 | c.5294C>T p.T1765M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs936423148, COSV99348309; called by muse, mutect2, varscan2
- NOL7 | c.714dup p.Q239Tfs*7 | Frame Shift Ins (INS) | VAF 13/34 reads (38%) | catalogued as rs544905440; called by mutect2, varscan2
- NOS3 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs772317436, COSV52488530; called by muse, mutect2, varscan2
- NPC1L1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV99213570; called by muse, mutect2, varscan2
- NUP188 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV65364370; called by muse, mutect2, varscan2
- NUP50 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV100754420; called by muse, mutect2, varscan2
- NUP58 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101098925; called by muse, mutect2, varscan2
- OPLAH | c.1311C>A p.F437L | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.543); catalogued as COSV101470754, COSV101470962; called by muse, mutect2, varscan2
- OR1N1 | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100509849, COSV59195782; called by muse, mutect2, varscan2
- OR4D9 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100260013, COSV61435202; called by muse, mutect2
- OR4S1 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100180306; called by muse, mutect2, varscan2
- PABPC1L | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs770340631, COSV99407790, COSV99408213; called by muse, mutect2, varscan2
- PASK | c.3031G>A p.G1011S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746309155, COSV52154877; called by muse, mutect2, varscan2
- PATJ | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV100335023; called by muse, mutect2, varscan2
- PCM1 | c.2938C>T p.R980W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750977185, COSV61517125; called by muse, mutect2, varscan2
- PDGFRB | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs755109587, COSV99940974; called by muse, mutect2, varscan2
- PDS5B | c.1180A>T p.R394* | Nonsense Mutation (SNP) | VAF 32/63 reads (51%) | catalogued as rs750827034, COSV59724936; called by muse, mutect2, varscan2
- PGBD4 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.53); catalogued as COSV56628088; called by muse, mutect2
- PHF10 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV100179250; called by muse, mutect2, varscan2
- PHF20 | c.2245G>A p.V749M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1346752698, COSV100926750; called by muse, mutect2, varscan2
- PKMYT1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.627); catalogued as rs780368070, COSV99234188; called by muse, mutect2, varscan2
- PLA2R1 | c.4176del p.G1393Dfs*13 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs1441058887; called by mutect2, pindel, varscan2
- PLAA | c.2189G>A p.S730N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as COSV101263572; called by muse, mutect2, varscan2
- PLEKHA6 | c.3011G>A p.R1004H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747483359, COSV99692819; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHM2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs775719327, COSV101009210; called by muse, mutect2, varscan2
- PLXNA1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.287); catalogued as COSV99303988; called by muse, mutect2, varscan2
- PLXND1 | c.3736C>T p.Q1246* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV60720830; called by muse, mutect2, varscan2
- PNPLA7 | c.2851G>A p.G951S | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as rs140666042; called by muse, mutect2, varscan2
- PNPLA7 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150851825; called by muse, mutect2, varscan2
- POLR3B | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as rs766728879, COSV99943882; called by muse, mutect2, varscan2
- POTEF | c.4G>C p.V2L | Missense Mutation (SNP) | VAF 100/205 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV100665367, COSV62543579; called by muse, varscan2
- PPL | c.2163-2A>G p.X721_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100631085; called by muse, mutect2, varscan2
- PPM1B | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs191178306, COSV99175752; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs758484975; called by mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 23/48 reads (48%) | catalogued as rs781858060; called by mutect2, varscan2
- PTPN18 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs377115203, COSV51558247; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 23/46 reads (50%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RAB36 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99321235; called by muse, mutect2, varscan2
- RAD51AP2 | c.1959del p.F653Lfs*20 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as COSV67588191; called by mutect2, pindel, varscan2
- RASL10B | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782005346; called by muse, mutect2, varscan2
- RBBP8 | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147143633; called by muse, mutect2, varscan2
- RBM33 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs1441488319, COSV100265760; called by muse, mutect2, varscan2
- RIF1 | c.6503G>A p.R2168H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1270684875, COSV54612993; called by muse, mutect2, varscan2
- RNF14 | c.1062A>G p.A354= | Splice Region (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100641308; called by muse, mutect2, varscan2
- RNF213 | c.6350G>A p.R2117H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs376262420; called by muse, mutect2, varscan2
- ROBO1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422415265, COSV71392568; called by muse, varscan2
- RPAP2 | c.1477A>G p.I493V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101528689; called by muse, mutect2, varscan2
- RREB1 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100619877; called by muse, mutect2, varscan2
- RUNX3 | c.566A>G p.D189G | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV100137119; called by muse, mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCCPDH | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100829748; called by muse, mutect2, varscan2
- SCN10A | c.4981G>A p.A1661T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760392111, COSV101479544; called by muse, mutect2, varscan2
- SDK1 | c.896del p.P299Rfs*18 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | catalogued as COSV101268876; called by mutect2, pindel, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs750651342; called by mutect2, varscan2
- SH3GL2 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101014855; called by muse, mutect2, varscan2
- SH3KBP1 | c.288C>T p.G96= | Splice Region (SNP) | VAF 17/34 reads (50%) | catalogued as rs746105574, COSV65642809; called by muse, mutect2, varscan2
- SLC17A6 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54138033, COSV99580837; called by muse, mutect2
- SLC7A1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756051752, COSV66331217; called by muse, mutect2, varscan2
- SLC7A13 | c.372del p.S126Afs*20 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as COSV52536834; called by mutect2, pindel, varscan2
- SLITRK2 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as COSV59429934; called by muse, mutect2, varscan2
- SMYD1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.649); catalogued as COSV101352527, COSV70224640; called by muse, mutect2, varscan2
- SNX2 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65348294; called by muse, mutect2, varscan2
- SPPL2B | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375876911, COSV101194695; called by muse, varscan2
- SV2B | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs746858920, COSV100370592; called by muse, mutect2, varscan2
- TBX2 | c.411del p.F138Sfs*17 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as COSV99538794; called by mutect2, pindel, varscan2
- TCEA3 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs777318907, COSV71532059; called by muse, mutect2, varscan2
- TCF4 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM125348, COSV61906615; called by muse, mutect2, varscan2
- TCF7 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1188626530, COSV100390202; called by muse, mutect2, varscan2
- TDP1 | c.1566G>T p.W522C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100188017; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | catalogued as rs763321097; called by mutect2, varscan2
- TESK2 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100517743; called by muse, mutect2, varscan2
- THOP1 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.306); catalogued as rs771666514, COSV57019745; called by muse, mutect2, varscan2
- THSD7B | c.3508G>A p.D1170N (on ENST00000272643; = p.D1168N on NM_001316349.2) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); catalogued as COSV55672843, COSV99758439; called by muse, mutect2, varscan2
- TICAM1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99941292; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs754390908; called by mutect2, varscan2
- TP73 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as rs530995550, COSV60698163; called by muse, mutect2, varscan2
- TRIM55 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99397260; called by muse, mutect2, varscan2
- TRMT1 | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV99679254; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPV4 | c.2308G>A p.G770S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1179327696, COSV99925098; called by muse, mutect2, varscan2
- TTN | c.66619C>T p.H22207Y (on ENST00000591111; = p.H14783Y on NM_003319.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | PolyPhen benign (0.322); catalogued as COSV100631176; called by muse, mutect2, varscan2
- TTN | c.5763A>G p.I1921M (on ENST00000591111; = p.I1875M on NM_003319.4) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | PolyPhen benign (0.001); catalogued as COSV100631178; called by muse, mutect2, varscan2
- TXNDC11 | c.1307C>T p.P436L (on ENST00000356957 / NM_001303447.2; = p.P409L on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs765281874, COSV51600602; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCRFS1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100508189; called by muse, mutect2, varscan2
- USP39 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777638540, COSV60383143; called by muse, mutect2, varscan2
- VN1R4 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 47/97 reads (48%) | catalogued as COSV100237610; called by muse, mutect2, varscan2
- VPS16 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100988636; called by muse, mutect2, varscan2
- VPS4A | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99652146; called by muse, mutect2, varscan2
- VWF | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as rs772554807, COSV99780239; called by muse, mutect2, varscan2
- XIAP | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.963); catalogued as COSV100848991; called by muse, mutect2, varscan2
- XIRP2 | c.3913G>C p.E1305Q (on ENST00000628543; = p.E1480Q on NM_152381.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV99747767; called by muse, mutect2
- ZBTB41 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.595); catalogued as rs755381458, COSV66359137, COSV66359283; called by muse, mutect2, varscan2
- ZBTB49 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs770871353, COSV61926078; called by muse, mutect2, varscan2
- ZFP36L1 | c.812del p.G271Vfs*36 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs1421733622; called by mutect2, pindel, varscan2
- ZMIZ2 | c.2340del p.I781Sfs*12 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs1279929143; called by mutect2, pindel, varscan2
- ZMYM5 | c.1388del p.K463Rfs*11 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs1392316624; called by mutect2, pindel, varscan2
- ZNF254 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs532366225, COSV100741795; called by muse, mutect2, varscan2
- ZNF275 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782081441, COSV100936467; called by muse, mutect2, varscan2
- ZNF324 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs566407024, COSV99543502; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF653 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs756913310, COSV99542364; called by muse, mutect2, varscan2
- AC005324.2 | c.212del p.E71Gfs*17 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- C1QTNF2 | c.278del p.P93Qfs*9 (on ENST00000393975; = p.P48Qfs*9 on NM_031908.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- C6orf118 | c.403del p.Q135Rfs*48 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- CACNA2D3 | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC186 | c.2600del p.N867Ifs*4 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- CCT2 | c.510del p.K170Nfs*13 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- CEACAM21 | c.6del p.S5_?2 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- CWC22 | c.706del p.R236Gfs*2 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- CWC25 | c.8del p.G3Afs*4 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- EFCAB12 | c.10_12dup p.D4dup | In Frame Ins (INS) | VAF 28/62 reads (45%) | called by mutect2, varscan2
- ESPNL | c.1028del p.P343Hfs*46 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- FAM83E | c.889del p.Q297Rfs*6 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, pindel, varscan2
- HSD17B14 | c.786del p.V263Wfs*20 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- IGHV3-38 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 34/40 reads (85%) | called by mutect2, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- KMT2D | c.2657del p.P886Lfs*44 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | called by mutect2, pindel, varscan2
- MMS22L | c.2098_2099del p.Q700Vfs*6 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- MPL | c.408del p.S137Vfs*29 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- MYO16 | c.2768_2769del p.K923Rfs*14 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- MYO9B | c.6450del p.A2151Pfs*12 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.648del p.K216Nfs*6 (on ENST00000280352 / NM_001082970.2; = p.K217Nfs*6 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1352_1356delinsTC p.E451_Y452delinsV (on ENST00000521381 / NM_181523.3; = p.E181_Y182delinsV on NM_181504.4) | In Frame Del (DEL) | VAF 9/30 reads (30%) | called by pindel, varscan2*
- PLD5 | c.966_968del p.R322del (on ENST00000442594; = p.R260del on NM_001195811.1 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- PRRC2A | c.5052del p.K1685Rfs*9 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- QTRT2 | c.1016del p.K339Sfs*10 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- RET | c.3142del p.L1048Sfs*61 (on ENST00000355710 / NM_020975.6; = p.L1048Sfs*60 on NM_020630.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- SH3RF3 | c.1760del p.P587Qfs*123 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.3941del p.K1314Rfs*23 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- SLCO5A1 | c.663del p.Y222Tfs*6 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- SMC4 | c.3686del p.N1229Mfs*19 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- TDRD5 | c.1907del p.L636Cfs*16 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | called by mutect2, pindel, varscan2
- TDRD5 | c.2870dup p.L957Ffs*43 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- TPSB2 | c.182del p.G61Afs*10 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- UBR5 | c.116del p.P39Lfs*2 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- USF3 | c.2430_2431insC p.A811Rfs*19 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | called by mutect2, pindel*, varscan2
- USP38 | c.1461del p.K487Nfs*57 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- ZNF12 | c.1960del p.T654Lfs*35 (on ENST00000405858 / NM_016265.4; = p.T616Lfs*35 on NM_006956.3) | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- ZNF518A | c.268_269del p.V90Kfs*11 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- ZNF518A | c.3760del p.I1254Ffs*85 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, varscan2
- ZNF75D | c.839del p.N280Mfs*29 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- AC008397.2 | c.813C>T p.T271= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs1455152053, COSV99442306; called by muse, mutect2, varscan2
- AC136428.1 | c.294G>A p.P98= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs374727759; called by muse, mutect2, varscan2
- ACTN1 | c.924C>T p.A308= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as rs765652494, COSV99518563; called by muse, mutect2, varscan2
- ADAMTS3 | c.2208T>C p.P736= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99712138; called by muse, mutect2, varscan2
- ADORA2A | c.93G>A p.V31= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100418162; called by muse, mutect2, varscan2
- AGPAT2 | c.783G>A p.K261= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs761143874, COSV100452057, COSV100452073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH4 | c.432G>A p.G144= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99479567, COSV99479573; called by muse, mutect2, varscan2
- ATM | c.4515C>T p.A1505= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs540798997, COSV99592047; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCL11A | c.1134C>T p.H378= (on ENST00000335712 / NM_001365609.1; = p.H412= on NM_018014.4) | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs1392606372, COSV59638590; called by muse, mutect2, varscan2
- CAST | c.1326G>A p.G442= (on ENST00000341926; = p.G525= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV57790935; called by muse, mutect2, varscan2
- CDH19 | c.1746C>T p.C582= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV50956764, COSV50967294; called by muse, mutect2, varscan2
- CELSR1 | c.4098C>A p.L1366= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99420128; called by muse, mutect2, varscan2
- CGREF1 | c.838C>T p.L280= (on ENST00000260595; = p.L297= on NM_006569.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99565426; called by muse, mutect2, varscan2
- CITED2 | c.669C>T p.I223= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100863130, COSV62726395; called by muse, mutect2, varscan2
- COPS7B | c.348G>A p.L116= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100602323; called by muse, mutect2, varscan2
- CUX2 | c.1752G>A p.S584= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs539297356, COSV99920369; called by muse, mutect2, varscan2
- CYP1B1 | c.24C>T p.N8= | Silent (SNP) | VAF 39/309 reads (13%) | catalogued as rs142995558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK4 | c.2079G>A p.E693= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101447990; called by muse, mutect2, varscan2
- EP400 | c.7068C>T p.I2356= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs765442346, COSV57770007; called by muse, mutect2, varscan2
- FAM20A | c.945C>T p.F315= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV99873524; called by muse, mutect2, varscan2
- FASN | c.1155C>T p.G385= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1214333176, COSV100148353; called by muse, mutect2, varscan2
- FAT1 | c.3879C>T p.D1293= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs779121846, COSV71673058; called by muse, mutect2, varscan2
- FOXD4L4 | c.822G>A p.S274= | Silent (SNP) | VAF 47/127 reads (37%) | called by muse, mutect2
- FOXJ1 | c.684C>T p.A228= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs775340485, COSV53944755; called by muse, varscan2
- FOXO3 | c.990C>T p.S330= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100670228; called by muse, mutect2, varscan2
- FRYL | c.8064C>T p.R2688= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99978255; called by muse, mutect2, varscan2
- GPR75 | c.1134G>A p.R378= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100766469; called by muse, mutect2, varscan2
- HAS2 | c.855A>G p.G285= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100392220; called by muse, mutect2, varscan2
- HECW1 | c.2235G>A p.A745= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs760339051, COSV101224355; called by muse, mutect2, varscan2
- HMGB3 | c.348C>T p.P116= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs782232648, COSV57487099; called by muse, mutect2, varscan2
- IGLV1-47 | c.144C>T p.I48= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs3206741; called by muse, mutect2, varscan2
- IGSF3 | c.744C>T p.A248= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs752695526, COSV100605126; called by muse, mutect2, varscan2
- IL4I1 | c.1641C>T p.S547= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1190391068, COSV99680955; called by muse, mutect2, varscan2
- ISLR2 | c.1359G>A p.P453= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs147968872, COSV100679792; called by muse, mutect2, varscan2
- JDP2 | c.129C>T p.L43= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs562181704, COSV99966819; called by muse, mutect2, varscan2
- JPH1 | c.849C>T p.G283= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV60611668, COSV60614068; called by muse, mutect2, varscan2
- KCNQ3 | c.2220G>A p.T740= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs758265549, COSV66464762; called by muse, mutect2, varscan2
- KIF15 | c.3243A>G p.K1081= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100393283; called by muse, varscan2
- KMT2D | c.8565G>A p.A2855= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs780023354, COSV99985975; called by muse, mutect2, varscan2
- LAS1L | c.324T>C p.T108= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100408698; called by muse, mutect2, varscan2
- LMO7 | c.3654G>A p.R1218= (on ENST00000357063; = p.R899= on NM_005358.5) | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV100413878; called by muse, mutect2, varscan2
- LRFN2 | c.42G>A p.A14= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs774848570, COSV100599460; called by muse, mutect2, varscan2
- LRIG1 | c.1359G>A p.P453= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1298429558, COSV56244638; called by muse, mutect2, varscan2
- LRRN2 | c.1545C>T p.G515= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs1558391231, COSV100912976; called by muse, mutect2
- MEDAG | c.660A>G p.K220= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100995332; called by muse, mutect2, varscan2
- MEF2D | c.1413C>T p.S471= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100560353; called by muse, mutect2, varscan2
- MELK | c.1395T>C p.T465= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs768370812, COSV99975125; called by muse, varscan2
- METTL7A | c.60C>T p.Y20= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100153732; called by muse, mutect2, varscan2
- MYBPC2 | c.2766C>A p.T922= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100732032, COSV63093244; called by muse, mutect2, varscan2
- MYEOV | c.18C>T p.C6= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs770876807, COSV100456675, COSV100456746; called by muse, mutect2, varscan2
- MYLK | c.4245A>G p.P1415= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100659673; called by muse, mutect2, varscan2
- MYOM2 | c.633A>G p.V211= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100038455; called by muse, mutect2, varscan2
- NLGN3 | c.2463G>A p.L821= (on ENST00000358741 / NM_181303.2; = p.L801= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100705066; called by muse, mutect2, varscan2
- NPC1 | c.1533G>A p.T511= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs778890495, COSV52578750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRK | c.1473G>A p.L491= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99689223; called by muse, mutect2, varscan2
- NUB1 | c.1632G>A p.Q544= (on ENST00000568733 / NM_001243351.1; = p.Q530= on NM_016118.4) | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV57837768; called by muse, mutect2, varscan2
- OR1S1 | c.183T>C p.A61= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100515495; called by muse, mutect2, varscan2
- OR4N2 | c.264G>A p.A88= | Silent (SNP) | VAF 55/158 reads (35%) | catalogued as rs144051874; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.444G>A p.Q148= (on ENST00000259318 / NM_001136562.3; = p.Q379= on NM_007203.5) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1293371434, COSV99395779; called by muse, mutect2, varscan2
- PAPPA2 | c.885G>A p.P295= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs771539594, COSV100867195; called by muse, mutect2, varscan2
- PCDH15 | c.3708C>T p.A1236= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs374185988; called by muse, mutect2, varscan2
- PCDHA12 | c.2253G>A p.S751= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV56474896; called by muse, mutect2, varscan2
- PCDHB10 | c.1710G>A p.A570= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV53375897; called by muse, mutect2, varscan2
- PDE1A | c.279C>A p.V93= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100116488; called by muse, mutect2
- PHC3 | c.1632A>G p.S544= (on ENST00000494943 / NM_001308116.2; = p.S556= on NM_024947.4) | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV101520193; called by muse, mutect2, varscan2
- PKD1 | c.11187C>T p.H3729= (on ENST00000262304 / NM_001009944.3; = p.H3728= on NM_000296.4) | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as rs369801323; called by muse, mutect2, varscan2
- PRDM1 | c.1710C>T p.N570= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs774601665, COSV64846945; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3801C>T p.P1267= (on ENST00000330843 / NM_001002814.3; = p.P633= on NM_025151.5) | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as COSV99770529; called by muse, mutect2, varscan2
- RAPGEF1 | c.213A>G p.A71= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100940821; called by muse, mutect2, varscan2
- RAPH1 | c.2850T>C p.P950= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV55586303; called by muse, mutect2, varscan2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs1190794791, COSV60978927; called by muse, mutect2, varscan2
- RIMS2 | c.4566C>T p.I1522= (on ENST00000666250 / NM_001348490.2; = p.I1093= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs267601696, COSV51668205; called by muse, mutect2, varscan2
- ROR2 | c.1377G>A p.Q459= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100995680, COSV100996125; called by muse, mutect2, varscan2
- RPAP3 | c.1119T>C p.F373= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV99139568; called by muse, mutect2, varscan2
- SLC22A13 | c.348T>C p.P116= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100314691; called by muse, mutect2, varscan2
- SLC46A3 | c.738C>T p.Y246= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1282237026, COSV99906543; called by muse, mutect2, varscan2
- SLC8A1 | c.2421C>T p.S807= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs1459415242, COSV100247500; called by muse, mutect2, varscan2
- SPACA1 | c.69C>T p.G23= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99389795; called by muse, mutect2
- SYK | c.675G>A p.K225= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV101002633; called by muse, mutect2, varscan2
- SYVN1 | c.1599C>T p.P533= (on ENST00000377190 / NM_172230.3; = p.P532= on NM_032431.3) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs1475158073, COSV99589291; called by muse, mutect2, varscan2
- TAC4 | c.129C>T p.G43= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs370585916; called by muse, mutect2, varscan2
- TFR2 | c.1831C>T p.L611= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV99774751; called by muse, mutect2
- TIMM17B | c.378T>C p.I126= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1557039098, COSV99504581; called by muse, mutect2, varscan2
- TMEM143 | c.771G>A p.T257= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs566888668, COSV99507572; called by muse, mutect2, varscan2
- TRPV2 | c.1857C>T p.R619= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs372686966; called by muse, varscan2
- TUBG1 | c.108C>T p.I36= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1367061332, COSV99258942; called by muse, mutect2, varscan2
- UCP3 | c.480C>T p.S160= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs371369161; called by muse, mutect2, varscan2
- WDR24 | c.2256G>A p.A752= (on ENST00000248142; = p.A622= on NM_032259.4) | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV99555470; called by muse, mutect2, varscan2
- WDR27 | c.1323C>A p.S441= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV61218147; called by muse, mutect2, varscan2
- ZNF133 | c.1911G>A p.Q637= (on ENST00000316358 / NM_001352454.2; = p.Q636= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100315680; called by muse, mutect2, varscan2
- ZNF750 | c.1284A>G p.E428= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99489974; called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 11/22 reads (50%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- C10orf71 | c.*136del | 3'UTR (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- C16orf91 | c.*266G>A | 3'UTR (SNP) | VAF 8/18 reads (44%) | catalogued as rs1333740585, COSV100113789; called by muse, mutect2, varscan2
- LRRC10 | c.*1G>T | 3'UTR (SNP) | VAF 39/92 reads (42%) | catalogued as COSV100825529; called by muse, mutect2, varscan2
- MBOAT2 | c.*2C>T | 3'UTR (SNP) | VAF 19/52 reads (37%) | catalogued as rs772543319, COSV100019678; called by muse, mutect2, varscan2
- PFKL | c.86-824G>A | Intron (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100827305; called by muse, mutect2
- STXBP1 | c.1702+1850T>C | Intron (SNP) | VAF 22/34 reads (65%) | catalogued as COSV100964638; called by muse, mutect2, varscan2
- UVSSA | c.*9237G>A | 3'UTR (SNP) | VAF 90/248 reads (36%) | catalogued as rs753921780, COSV100246344; called by muse, mutect2, varscan2
- ZNF271P | n.2001G>A | RNA (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
